Somatic mutation profile of tumor specimen TARGET-10-PAPHDX-09A (aliquot TARGET-10-PAPHDX-09A-01D) from TARGET case TARGET-10-PAPHDX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (791 days).
Specimen TARGET-10-PAPHDX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f1a1629-553a-4bcd-b590-3d23df99be69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPHDX-10A (Blood Derived Normal), aliquot TARGET-10-PAPHDX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82cd464f-044d-4c37-9826-c35bf9017671

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Nonsense Mutation 2, Silent 2, 3'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL11B | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs201749852; called by muse, mutect2, varscan2
- CTNND2 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs185561753; called by muse, mutect2, varscan2
- DOCK5 | c.2608C>T p.R870* | Nonsense Mutation (SNP) | VAF 8/92 reads (9%) | catalogued as rs1298921901, COSV52397358; called by muse, mutect2
- FLT3 | c.2600T>G p.I867S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV54069897; called by muse, mutect2, varscan2
- CD109 | c.848C>A p.T283K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGLV4-60 | c.361_362insTTCCGCCCC | In Frame Ins (INS) | VAF 19/54 reads (35%) | called by mutect2, pindel, varscan2
- KIF18B | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
- UACA | c.854A>G p.N285S | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2
- AHNAK2 | c.1302C>T p.A434= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs761805012, COSV60909250; called by muse, mutect2, varscan2
- MADCAM1 | c.306C>T p.T102= | Silent (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- ADRA2C | c.*57C>T | 3'UTR (SNP) | VAF 11/38 reads (29%) | catalogued as COSV57467557; called by muse, mutect2
